Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96Q, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96Q-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

ICD-O-3
Thymoma, type AB,
malignant 8582/3
Site Thymus C32.9
4/14/14

Pathology Report-Summary:

Material:

Tumor: 1.6 x 1.4 cm

Diagnosis:

Type A/B-Thymoma

pT2, pN0 (0/6)

Masaoka: IIa

Immunohistochemistry

epithelial cells positive for: CK 5/6, partially for KL1

epithelial cells negative for: CD5, CD117

CD1a-, CD99-positive immature T-lymphocytes, negative staining for CD20, CD117
CD3-, CD5-positive mature T-lymphocytes

Source: NCI Genomic Data Commons file 569350dc-45da-4c8e-b870-e9cc7475a28b (TCGA-ZB-A96Q.81A739C1-DA8F-4088-8B4D-1622E9A0218E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).